Surgical pathology report (de-identified scan), TCGA case TCGA-55-8620, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8620-01A (Primary Tumor).

DIAGNOSIS

DIAGNOSIS:

A. Level VII lymph node, excision:

One lymph node positive for metastatic carcinoma.

B. Lung, upper lobe, excision:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: Grade II-III, moderate to poorly differentiated.
3. Tumor site: Left upper lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 1.9 x 1.8 x 1.5 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Not identified.

Surgical Margin Status:

1. Tumor distance from parenchymal margin: 2.5 cm.
2. Tumor distance from pleural surface: 0.1 cm.

Lymph Node Status:

1. See parts A, C.
- Other:
1. pTNM stage: pT1a N1.

C. Level V and VI lymph nodes, excision:

Four lymph nodes, negative for metastatic disease.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Level VII lymph node
- B. Left upper lobe
- C. Level V and VI lymph nodes

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three formalin-filled containers labeled with the patient's name I _____.

A. Container A is additionally labeled level VII lymph node, and contains a 2.2 x 1.3 x 1.0 cm, yellow-tan, firm rubbery nodule consistent with lymph node. The specimen is bisected and entirely submitted in cassette A1, labeled _____.

B. Container B is additionally labeled left upper lobe and contains a 20.0 x 9.0 x 4.5 cm, purple-gray lung lobe. The pleura is remarkable for a 2.5 x 1.4 x 0.5 cm, area of umbilication which is inked blue. A 10.5 x 4.0 cm area of exposed parenchyma is identified. Within this area are multiple segments of

exposed bronchi and vasculature. Discrete masses are not identified. The bronchial and vascular margins were taken en face, and the surrounding parenchyma is inked black. The specimen is serially sectioned to reveal a 1.9 x 1.8 x 1.5 cm, ill-defined, gray-white, mass that approaches to within less than 0.1 cm of the inked pleura and to within 2.5 cm of the inked parenchymal margin. The remainder of the cut surface is comprised of beefy red, anthracotic and congested parenchyma with focal areas of emphysematous change. Discrete lymph nodes are not identified. Representative sections are submitted in cassettes B1-9, labeled _____, designated as follows: B1-2 -- en face vascular and bronchial margins; 3 -- inked parenchymal margin, perpendicular; 4-5 -- mass to inked pleura; 6-7 -- remainder of mass; 8 -- emphysematous change; 9 -- additional representative sections of parenchyma. Three genomics cassettes are also submitted, each labeled _____.

C. Container C is additionally labeled level V and VI lymph nodes, and contains a 3.4 x 2.3 x 1.0 cm, yellow-tan, lobulated fibrofatty soft tissue. On palpation, four firm fatty possible lymph nodes are identified ranging from 0.4 up to 1.8 cm in greatest dimension. They are entirely submitted in cassettes C1-2, labeled _____, designated as follows: C1 -- three whole possible lymph nodes; C2 -- one whole possible bisected lymph node.

Source: NCI Genomic Data Commons file 63bf6d0f-7854-4f2a-8c24-76e27f08a97c (TCGA-55-8620.D74A185A-8E07-46CA-861E-14B0012DDF22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).